TCGA case TCGA-QK-A6IH — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Gum; Tissue source site: Emory University - Winship Cancer Inst. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c1f286f6-d4a1-494a-88c8-ff8e2a3df2ce

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 65 years; Vital status: Alive.

Diagnoses (3)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C03.9; Tissue or organ of origin: Gum, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 65.5 years (23,936 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC clinical T: T4a; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T4b; AJCC pathologic N: N2b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node dissection method: Modified Radical Neck Dissection; Lymph node dissection site: Neck, Left.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: Microscopic Extension; Lymph nodes positive: 3; Lymph nodes tested: 32; Lymphatic invasion present: Yes; Margin status: Indeterminate; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 49 days; Days to treatment end: 84 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 49 days; Days to treatment end: 91 days; Treatment dose: 56 Gy; Number of fractions: 38; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 49 days; Days to treatment end: 91 days; Treatment dose: 46 Gy; Number of fractions: 38; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 49 days; Days to treatment end: 91 days; Treatment dose: 51 Gy; Number of fractions: 38; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Days to treatment end: 396 days (1.1 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Cetuximab; Days to treatment end: 396 days (1.1 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Cure; Days to treatment end: 91 days; Treatment outcome: Persistent Disease; Chemo concurrent to radiation: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment end: 396 days (1.1 years); Treatment outcome: Stable Disease.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS), site: Lung, NOS. Age at diagnosis: 66.2 years (24,164 days); Days to diagnosis: 228 days; Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS), site: Upper lobe, lung. Age at diagnosis: 66.2 years (24,184 days); Days to diagnosis: 248 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (4 entries)
- Day 228 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 228 days; Evidence of progression type: Convincing Image Source.
- Day 248 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Upper lobe, lung; Days to progression: 248 days; Evidence of progression type: Biopsy with Histologic Confirmation.
- Days to follow up: 508 days (1.4 years); Disease response: With Tumor.
- Days to follow up: 653 days (1.8 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QK-A6IH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 60 mg.
  Slide TCGA-QK-A6IH-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-QK-A6IH-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QK-A6IH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Anatomic organ subdivision: Alveolar Ridge; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymph node neck dissection indicator: Yes; Margin status: Close; Lymphovascular invasion: Yes; Tobacco smoking history indicator: 1; Alcohol history documented: Yes.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Drug treatment 4: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Drug treatment 5: Pharmaceutical therapy drug name: Erbitux.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Definitive treatment method: Concurrent Chemotherapy; Definitive treatment evidence disease after: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 653 days; disease-specific survival: no event (censored), 653 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 228 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-QK-A6IH-01A-11D-A31K-01): tumor purity 0.76, ploidy 1.82, whole-genome doublings 0.
